Gene-level copy-number profile of tumor specimen CDDP-ABKU-TTP2-A from CDDP_EAGLE case CDDP-ABKU, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 79 years.
Specimen CDDP-ABKU-TTP2-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d1bbaddf-f314-48b8-b7c9-a64323bb15eb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ABKU-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/8147e131-2224-4544-bd54-d4f256816d83

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 2,899; copy number 2: 53,110; copy number 3: 2,890.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:69,433,255–69,435,409, 1 gene: LINC01758.
- chr2:195,003,711–195,026,370, 1 gene: AC010983.1.
- chr8:43,672,823–43,674,591, 2 genes: AC139365.2, AC139365.1.
- chr10:38,783,004–38,783,108, 1 gene: AL590623.1.
- chr21:18,614,431–18,650,360, 1 gene (within-gene range 0–2): AF240627.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 50. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
